Somatic mutation profile of tumor specimen TCGA-YG-AA3P-06A (aliquot TCGA-YG-AA3P-06A-11D-A38G-08) from TCGA case TCGA-YG-AA3P, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 64.4 years (23,515 days).
Specimen TCGA-YG-AA3P-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bb5df7c-2083-4604-b4d1-46b634155270.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YG-AA3P-10A (Blood Derived Normal), aliquot TCGA-YG-AA3P-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d39c3c5-5e8f-4c7e-8de6-f457b621af1e

The open-access MAF lists 81 somatic variants for this specimen: 57 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 54, Silent 24, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 56/110 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913512, CM002803, COSV55387507, COSV55411978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.2278T>G p.F760V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101201220; called by muse, varscan2
- ALDH7A1 | c.1067A>G p.Q356R | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100778277; called by muse, mutect2, varscan2
- AOC1 | c.1853C>A p.A618E | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100710888; called by muse, mutect2, varscan2
- ARAP2 | c.2677A>G p.T893A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV100395017; called by muse, mutect2, varscan2
- ATP13A4 | c.1262T>G p.V421G | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99794968; called by muse, mutect2, varscan2
- BCAN | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV100228327; called by muse, mutect2, varscan2
- CAMTA2 | c.1520C>A p.P507Q | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100772748; called by muse, mutect2, varscan2
- CCDC66 | c.2570A>T p.Y857F (on ENST00000394672 / NM_001353147.1; = p.Y823F on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100414202; called by muse, mutect2, varscan2
- CCN3 | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.386); catalogued as COSV99423236; called by muse, mutect2, varscan2
- CFAP46 | c.7181G>A p.G2394D | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as COSV99585308; called by muse, mutect2, varscan2
- CLEC17A | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100355483; called by muse, mutect2, varscan2
- COL7A1 | c.5323C>T p.P1775S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.909); catalogued as rs759805736, COSV100097083; called by muse, mutect2, varscan2
- CRACDL | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs759415222, COSV101194103; called by muse, mutect2, varscan2
- DNAH9 | c.4583G>T p.G1528V | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99307138; called by muse, mutect2, varscan2
- ELOA | c.2314C>A p.P772T | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV101403797; called by muse, mutect2, varscan2
- ENAH | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0); catalogued as rs148381397; called by muse, mutect2, varscan2
- EZH2 | c.1012C>T p.L338F (on ENST00000460911 / NM_001203247.2; = p.L343F on NM_004456.5) | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.277); catalogued as COSV100236273; called by muse, mutect2, varscan2
- FBXO31 | c.826T>A p.Y276N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100291541; called by muse, mutect2, varscan2
- GNAI3 | c.670T>G p.C224G | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100879937; called by muse, mutect2, varscan2
- H6PD | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV66230988; called by muse, mutect2, varscan2
- HTR3E | c.616C>T p.R206W (on ENST00000415389 / NM_001256613.1; = p.R221W on NM_182589.2) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs375789936, COSV100094334, COSV58948118; called by muse, mutect2, varscan2
- ITPRID1 | c.2068G>T p.G690W | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100087126; called by muse, mutect2
- KAT6B | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as rs752855653, COSV99768084; called by muse, mutect2, varscan2
- KIF17 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs371219583, COSV56118638; called by muse, mutect2, varscan2
- MAST1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs772486947, COSV99263417; called by muse, mutect2, varscan2
- MGST1 | c.38T>G p.F13C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99163179; called by muse, mutect2, varscan2
- MOB3C | c.514A>G p.S172G | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99596399; called by muse, mutect2, varscan2
- MOCOS | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs141550556; called by muse, mutect2, varscan2
- NLRP11 | c.2755C>G p.L919V | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100789784; called by muse, mutect2, varscan2
- NPAP1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.143); catalogued as rs1179838693, COSV100275800, COSV61508196; called by muse, mutect2, varscan2
- OBSCN | c.4919C>T p.A1640V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.106); catalogued as rs764034660; called by muse, mutect2, varscan2
- OR52E8 | c.491C>G p.P164R | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101190649; called by muse, mutect2, varscan2
- OR5T2 | c.73A>T p.N25Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100506927, COSV100507011; called by muse, mutect2, varscan2
- PCIF1 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 141/217 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV100533249; called by muse, mutect2, varscan2
- PCLO | c.7553A>G p.Q2518R | Missense Mutation (SNP) | VAF 99/140 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV100435427; called by muse, mutect2, varscan2
- PHLDB2 | c.3117G>C p.E1039D (on ENST00000393925 / NM_001134439.2; = p.E996D on NM_145753.2) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67308910; called by muse, mutect2, varscan2
- PIGK | c.1175A>C p.K392T | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100892232; called by muse, mutect2, varscan2
- PITX2 | c.355G>T p.A119S (on ENST00000354925 / NM_001204397.1; = p.A126S on NM_000325.6) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.989); catalogued as COSV100146395; called by muse, mutect2, varscan2
- PLK1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs747122668, COSV55620742, COSV99892028; called by muse, mutect2, varscan2
- PPFIA1 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs748263753, COSV54136686; called by muse, mutect2, varscan2
- PTGFRN | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs749073852, COSV101277421; called by muse, mutect2, varscan2
- PTPRZ1 | c.4157C>T p.S1386F | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.259); catalogued as COSV101100566; called by muse, mutect2, varscan2
- RAD17 | c.1637T>G p.L546R (on ENST00000380774 / NM_133339.2; = p.L535R on NM_002873.1) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99281649; called by muse, mutect2, varscan2
- RIN1 | c.2151G>T p.E717D | Missense Mutation (SNP) | VAF 71/81 reads (88%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV100254855, COSV60928334; called by muse, mutect2, varscan2
- ROS1 | c.3386G>C p.R1129T | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV100877512, COSV100877690; called by muse, mutect2, varscan2
- SDK2 | c.2452C>A p.Q818K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101168140; called by muse, mutect2, varscan2
- SERPINA10 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs2232697, COSV100003661; called by muse, mutect2, varscan2
- SNCAIP | c.2632A>C p.N878H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99749697; called by muse, mutect2, varscan2
- TACR3 | c.586T>A p.S196T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as COSV100510748; called by muse, mutect2, varscan2
- UGT2B15 | c.651T>A p.H217Q | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100592401; called by muse, mutect2, varscan2
- ZNF528 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); catalogued as rs758069968, COSV64619312; called by muse, mutect2, varscan2
- ZNF782 | c.1249A>C p.T417P | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100001533; called by muse, mutect2, varscan2
- CD8A | c.590_606del p.L197Hfs*46 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- GPR173 | c.51dup p.P18Tfs*23 | Frame Shift Ins (INS) | VAF 25/35 reads (71%) | called by mutect2, pindel, varscan2
- IGLV1-50 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- PITPNM1 | c.3548dup p.R1184Efs*36 | Frame Shift Ins (INS) | VAF 13/127 reads (10%) | called by mutect2, pindel
- ACTG1 | c.645G>A p.K215= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs543202804, COSV100112024; called by muse, mutect2, varscan2
- ANO3 | c.1803T>C p.C601= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV99884500; called by muse, mutect2, varscan2
- CARD6 | c.1071T>C p.D357= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99621070; called by muse, mutect2, varscan2
- CFHR2 | c.399C>A p.G133= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV66381246; called by muse, mutect2, varscan2
- CHPF2 | c.1923G>A p.G641= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV50389071, COSV99223252; called by muse, mutect2
- DICER1 | c.3243A>G p.G1081= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV100602374; called by muse, mutect2, varscan2
- FAM219B | c.147C>A p.T49= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV100715274; called by muse, mutect2, varscan2
- FNDC4 | c.186G>A p.S62= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs772678108, COSV99253991; called by muse, mutect2, varscan2
- HASPIN | c.2103C>T p.F701= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV99561339; called by muse, mutect2, varscan2
- KLK15 | c.639G>T p.L213= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100032872; called by muse, mutect2, varscan2
- LILRB4 | c.1281G>A p.E427= (on ENST00000391733 / NM_001278428.3; = p.E426= on NM_001278426.3) | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV99554012; called by muse, mutect2, varscan2
- NCR1 | c.885C>A p.G295= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV52558605; called by muse, mutect2, varscan2
- PCDHA1 | c.1353C>T p.N451= | Silent (SNP) | VAF 51/221 reads (23%) | catalogued as rs143660641; called by muse, mutect2, varscan2
- PDS5B | c.876T>G p.V292= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV100221295; called by muse, mutect2, varscan2
- PELI3 | c.507C>T p.S169= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs144457255, COSV100291867; called by muse, mutect2, varscan2
- PTCHD4 | c.699C>A p.A233= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV100261367; called by muse, mutect2, varscan2
- RGS17 | c.582A>G p.Q194= | Silent (SNP) | VAF 56/62 reads (90%) | catalogued as rs1488959853, COSV99243243; called by muse, mutect2, varscan2
- ROS1 | c.4507T>C p.L1503= | Silent (SNP) | VAF 32/36 reads (89%) | catalogued as COSV100877510; called by muse, mutect2, varscan2
- SERINC1 | c.1233A>G p.E411= | Silent (SNP) | VAF 22/23 reads (96%) | catalogued as COSV100305328; called by muse, mutect2, varscan2
- SLCO4A1 | c.1116G>T p.L372= | Silent (SNP) | VAF 19/187 reads (10%) | catalogued as COSV99414960; called by muse, mutect2
- TLL1 | c.1842T>C p.C614= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99288411; called by muse, varscan2
- ZNF347 | c.2004T>A p.L668= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV100498367; called by muse, mutect2, varscan2
- ZNF862 | c.1713C>T p.P571= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV99783668; called by muse, mutect2
- ZZEF1 | c.4041C>T p.R1347= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs747539432, COSV101067938; called by muse, mutect2, varscan2
